Somatic mutation profile of tumor specimen C3L-08236-01 (aliquot CPT0485000006) from CPTAC case C3L-08236, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 73.2 years (26,741 days).
Specimen C3L-08236-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 929011f9-51b2-4f60-a39d-6684a0dad130.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08236-31 (Blood Derived Normal), aliquot CPT0485150003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d414258-acfa-40f2-b0b4-5221796bafc8

The open-access MAF lists 85 somatic variants for this specimen: 57 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 26, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1, Intron 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL4 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 62/301 reads (21%) | catalogued as rs964532159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA5 | c.6301G>A p.E2101K | Missense Mutation (SNP) | VAF 109/655 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs370433088, COSV53357422; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 91/349 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS13 | c.3820C>T p.R1274C | Missense Mutation (SNP) | VAF 73/454 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs371964138; called by muse, mutect2, varscan2
- ARID3C | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 118/561 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs768367505; called by muse, mutect2, varscan2
- ASTN1 | c.3368C>T p.T1123M | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs369440281; called by muse, mutect2, varscan2
- CACNB2 | c.238C>T p.R80C (on ENST00000324631 / NM_201596.3; = p.R25C on NM_000724.4) | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56648726; called by muse, mutect2
- CASR | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 44/642 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as COSV56139996; called by muse, mutect2
- CD1B | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 114/453 reads (25%) | catalogued as rs370440810; called by muse, mutect2, varscan2
- CRTAC1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 87/423 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764021235, COSV53997045; called by muse, mutect2, varscan2
- DCAKD | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 107/492 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1422960944, COSV60830344; called by muse, mutect2, varscan2
- DIS3L | c.2035G>A p.E679K (on ENST00000319212 / NM_001143688.3; = p.E596K on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/535 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as rs747683969; called by muse, mutect2, varscan2
- DUOX1 | c.4231C>A p.Q1411K | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.027); catalogued as COSV52051330; called by muse, mutect2, varscan2
- GPHN | c.815G>A p.R272H (on ENST00000315266 / NM_001377519.1; = p.R305H on NM_020806.5) | Missense Mutation (SNP) | VAF 45/476 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs778622230, COSV59486287; called by muse, mutect2
- MPPE1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs574654136; called by muse, mutect2, varscan2
- MTOR | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as rs766996808; called by muse, mutect2, varscan2
- MYH2 | c.5360G>A p.R1787Q | Missense Mutation (SNP) | VAF 85/389 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs770182875, COSV55434133, COSV55439908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTSR2 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 158/465 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs1461394810, COSV60990387; called by muse, mutect2, varscan2
- NUP58 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 79/653 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs138242135; called by muse, mutect2, varscan2
- PCDHB12 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 79/434 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); catalogued as rs146148949; called by muse, mutect2, varscan2
- PDE4B | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 83/396 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201667673, COSV100304809, COSV58468345, COSV58486518; called by muse, mutect2, varscan2
- RRAGB | c.1019C>T p.P340L (on ENST00000262850 / NM_016656.4; = p.P312L on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV53328281; called by muse, mutect2, varscan2
- RTL1 | c.2467G>A p.V823M | Missense Mutation (SNP) | VAF 102/480 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1018029172, COSV101128241; called by muse, mutect2, varscan2
- RYR1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs748318655, COSV100615705, COSV62107125; called by muse, mutect2, varscan2
- SGCZ | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101170437, COSV66023119; called by muse, mutect2
- SHANK2 | c.3199C>T p.R1067W | Missense Mutation (SNP) | VAF 58/506 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555154169; called by muse, mutect2, varscan2
- SPTBN1 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 148/432 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.315); catalogued as rs1331965648, COSV61695290; called by muse, mutect2, varscan2
- TBC1D31 | c.2058C>G p.D686E | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs992085996; called by muse, mutect2
- ZFHX4 | c.2589C>T p.L863= | Splice Region (SNP) | VAF 50/239 reads (21%) | catalogued as rs918056522; called by muse, mutect2, varscan2
- ABCA10 | c.2628G>C p.Q876H | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- ABCA4 | c.4115A>G p.D1372G | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ACKR4 | c.527A>C p.Y176S | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALOX5 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPT4 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 85/477 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARID1A | c.2117T>C p.V706A | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASTN2 | c.2933A>C p.E978A (on ENST00000313400 / NM_001365069.1; = p.E927A on NM_014010.5) | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ATP10A | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- C20orf202 | c.147G>C p.Q49H | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CLDN3 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 75/582 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL19A1 | c.817T>C p.S273P | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- ERBB4 | c.2037C>G p.S679R | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- FAM81B | c.43dup p.R15Kfs*18 | Frame Shift Ins (INS) | VAF 39/226 reads (17%) | called by mutect2, pindel, varscan2
- FOXJ1 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- GALNT17 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GPR68 | c.436T>C p.W146R | Missense Mutation (SNP) | VAF 52/491 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IMMP2L | c.407C>G p.P136R | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LPL | c.1370A>C p.K457T | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); called by muse, mutect2
- NPFFR2 | c.1499G>A p.S500N | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NUP107 | c.1474G>C p.V492L | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- PALLD | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 77/335 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PSMD12 | c.510+1G>A p.X170_splice | Splice Site (SNP) | VAF 40/245 reads (16%) | called by muse, mutect2, varscan2
- REPIN1 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 58/567 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELENBP1 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPTBN5 | c.2755C>T p.L919F | Missense Mutation (SNP) | VAF 69/403 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SRRM2 | c.5019G>C p.R1673S | Missense Mutation (SNP) | VAF 107/501 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TCF4 | c.828T>G p.S276R | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TMX3 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2
- APCDD1L | c.735C>T p.S245= | Silent (SNP) | VAF 84/795 reads (11%) | called by muse, mutect2, varscan2
- BNC2 | c.639G>A p.L213= | Silent (SNP) | VAF 59/307 reads (19%) | called by muse, mutect2, varscan2
- DAAM2 | c.36C>A p.G12= | Silent (SNP) | VAF 50/458 reads (11%) | called by muse, mutect2
- EIF3B | c.1908G>A p.A636= | Silent (SNP) | VAF 31/356 reads (9%) | catalogued as rs201791942, COSV62802862; called by muse, mutect2
- FAM13C | c.1597A>C p.R533= | Silent (SNP) | VAF 117/552 reads (21%) | called by muse, mutect2, varscan2
- GPC6 | c.1569C>T p.D523= | Silent (SNP) | VAF 50/698 reads (7%) | catalogued as rs778654460, COSV100989861, COSV100990054; called by muse, mutect2
- GRIA1 | c.1413G>A p.T471= | Silent (SNP) | VAF 76/372 reads (20%) | catalogued as rs374477331; called by muse, mutect2, varscan2
- GUCY1A2 | c.93G>C p.L31= | Silent (SNP) | VAF 83/437 reads (19%) | called by muse, mutect2, varscan2
- HHIPL1 | c.2073C>T p.F691= | Silent (SNP) | VAF 65/495 reads (13%) | catalogued as rs1342202509, COSV58089434; called by muse, mutect2, varscan2
- LAMA5 | c.6042C>T p.A2014= | Silent (SNP) | VAF 70/462 reads (15%) | catalogued as rs1049749036; called by muse, mutect2, varscan2
- LAMA5 | c.1266G>A p.S422= | Silent (SNP) | VAF 80/423 reads (19%) | catalogued as rs768591711; called by muse, mutect2, varscan2
- LCE2A | c.255C>T p.P85= | Silent (SNP) | VAF 78/812 reads (10%) | catalogued as rs372077582, COSV100909214; called by muse, mutect2
- LCE3C | c.243C>T p.G81= | Silent (SNP) | VAF 117/802 reads (15%) | catalogued as rs1557786523, COSV61610197; called by muse, mutect2, varscan2
- LZTS1 | c.114C>T p.S38= | Silent (SNP) | VAF 45/418 reads (11%) | catalogued as rs777378841, COSV56116342, COSV56116500; called by muse, mutect2, varscan2
- MRGPRX1 | c.345C>T p.A115= | Silent (SNP) | VAF 88/766 reads (11%) | catalogued as rs766378365, COSV57107000, COSV57110417; called by muse, mutect2, varscan2
- MYH9 | c.4974C>T p.R1658= | Silent (SNP) | VAF 84/338 reads (25%) | catalogued as rs776733292, COSV53385907; called by muse, mutect2, varscan2
- MYO15A | c.2049G>A p.A683= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as COSV99231387; called by muse, mutect2, varscan2
- NTRK3 | c.849G>A p.T283= | Silent (SNP) | VAF 81/466 reads (17%) | catalogued as rs775675734, COSV58124630; called by muse, mutect2, varscan2
- OR4D5 | c.579T>C p.F193= | Silent (SNP) | VAF 92/386 reads (24%) | called by muse, mutect2, varscan2
- OR6J1 | c.429C>T p.T143= | Silent (SNP) | VAF 69/345 reads (20%) | catalogued as rs1019865936; called by muse, mutect2, varscan2
- PCDHA3 | c.1554C>T p.Y518= | Silent (SNP) | VAF 128/710 reads (18%) | catalogued as rs957021626; called by muse, varscan2
- PPM1F | c.1092C>T p.D364= | Silent (SNP) | VAF 99/394 reads (25%) | catalogued as rs748505451; called by muse, mutect2, varscan2
- PROS1 | c.453A>T p.G151= | Silent (SNP) | VAF 57/310 reads (18%) | called by muse, mutect2, varscan2
- SMG1 | c.8898C>T p.G2966= | Silent (SNP) | VAF 50/590 reads (8%) | called by muse, mutect2
- TSC1 | c.396C>T p.G132= | Silent (SNP) | VAF 37/343 reads (11%) | catalogued as rs368922726; ClinVar: not provided; called by muse, mutect2, varscan2
- UBE2Z | c.459G>A p.R153= | Silent (SNP) | VAF 113/508 reads (22%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.1372-20G>A | Intron (SNP) | VAF 50/283 reads (18%) | catalogued as rs771060630; called by muse, mutect2, varscan2
- ZNF841 | c.-25C>T | 5'UTR (SNP) | VAF 107/351 reads (30%) | catalogued as rs1362573998, COSV63471762; called by muse, mutect2, varscan2
